Somatic mutation profile of tumor specimen TCGA-D5-6537-01A (aliquot TCGA-D5-6537-01A-11D-1719-10) from TCGA case TCGA-D5-6537, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 64.0 years (23,381 days).
Specimen TCGA-D5-6537-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c80d8506-1619-47f3-89e4-d5bbfbc6fee2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6537-10A (Blood Derived Normal), aliquot TCGA-D5-6537-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50563a9b-2be0-4978-a2fb-7d8202add880

The open-access MAF lists 116 somatic variants for this specimen: 89 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 23, Nonsense Mutation 4, Splice Region 2, Intron 2, Splice Site 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1875_1878del p.N627Lfs*2 | Frame Shift Del (DEL) | VAF 84/195 reads (43%) | catalogued as rs878853420; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNJ2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 433/1057 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473373, CM066888, COSV54664479; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 54/87 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1351_1362del p.G451_D454del | In Frame Del (DEL) | VAF 58/87 reads (67%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAMTSL2 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63203151; called by muse, mutect2, varscan2
- ADGRE3 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as rs149254238, COSV99506422; called by muse, mutect2, varscan2
- AP4M1 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57993757; called by muse, mutect2, varscan2
- APOA4 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.611); catalogued as rs983632449, COSV63359968; called by muse, mutect2, varscan2
- ASTN2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs138260564; called by muse, mutect2, varscan2
- ATP8B2 | c.189G>A p.A63= (on ENST00000672630; = p.A30= on NM_001005855.2) | Splice Region (SNP) | VAF 23/60 reads (38%) | catalogued as rs754348764, COSV59244535, COSV59248075; called by muse, mutect2, varscan2
- AXIN2 | c.530A>C p.E177A | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100196163, COSV61060431; called by muse, mutect2, varscan2
- BNIP2 | c.819A>T p.R273S | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV51105010; called by muse, mutect2, varscan2
- C1QTNF12 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57802166; called by muse, mutect2, varscan2
- C1orf127 | c.1328C>A p.A443E | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.324); catalogued as COSV65436305; called by muse, mutect2, varscan2
- CCR7 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs200794532, COSV55848442; called by muse, mutect2, varscan2
- CHP2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1445650566, COSV55649104; called by muse, mutect2, varscan2
- CHRNA1 | c.679C>T p.R227W (on ENST00000261007 / NM_001039523.3; = p.R202W on NM_000079.4) | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs528619587, COSV53681507; called by muse, mutect2, varscan2
- COG4 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60421114; called by muse, mutect2, varscan2
- COL27A1 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as rs562577846, COSV61921215; called by muse, mutect2, varscan2
- COL4A3 | c.4219G>T p.E1407* | Nonsense Mutation (SNP) | VAF 74/126 reads (59%) | catalogued as COSV67412540; called by muse, mutect2, varscan2
- COL4A5 | c.2173G>T p.G725* | Nonsense Mutation (SNP) | VAF 119/298 reads (40%) | catalogued as COSV60355750; called by muse, mutect2, varscan2
- CPSF1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs781809063, COSV62938835; called by muse, mutect2, varscan2
- CSMD1 | c.8339G>A p.R2780Q (on ENST00000520002; = p.R2779Q on NM_033225.6) | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as rs778214225, COSV100144951, COSV59277524; called by muse, mutect2, varscan2
- CTDP1 | c.2333C>T p.T778M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765240178, COSV50000302; called by muse, mutect2, varscan2
- CYP20A1 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as COSV61908964; called by muse, mutect2, varscan2
- DMBX1 | c.1046C>A p.P349H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV63601615, COSV63601712; called by muse, mutect2, varscan2
- DSCAM | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV68020323, COSV68028921; called by muse, mutect2, varscan2
- DVL3 | c.920T>C p.F307S | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57454721; called by muse, mutect2, varscan2
- DYRK3 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200726014, COSV65605326; called by muse, mutect2, varscan2
- ECD | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401443446, COSV65898536; called by muse, mutect2, varscan2
- EFCAB6 | c.4366G>A p.V1456I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV53057721; called by muse, mutect2, varscan2
- EHD4 | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV55003145, COSV55006385; called by muse, mutect2, varscan2
- EIF4EBP2 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV64667149; called by muse, mutect2, varscan2
- EPHA4 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 112/206 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436714812, COSV56025973, COSV56044090; called by muse, mutect2, varscan2
- F7 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750980786, CM940394, COSV100660989, COSV60644880; called by muse, mutect2, varscan2
- FAM153A | c.29-1G>C p.X10_splice | Splice Site (SNP) | VAF 36/272 reads (13%) | catalogued as COSV100646958, COSV100647055; called by mutect2, varscan2
- FAM174A | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV57061829; called by muse, mutect2, varscan2
- FRYL | c.5398T>C p.S1800P | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs146907203; called by muse, mutect2, varscan2
- GCC1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.095); catalogued as COSV50000151; called by muse, mutect2, varscan2
- GLUD2 | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 155/180 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.774); catalogued as COSV60151116; called by muse, mutect2, varscan2
- GMIP | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1213104382, COSV52554047; called by muse, mutect2, varscan2
- GRHPR | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as rs146603229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2A | c.2326G>T p.D776Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58019045, COSV58022891; called by muse, mutect2, varscan2
- IL32 | c.314C>T p.A105V (on ENST00000396890 / NM_001308078.4; = p.A59V on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs948189979, COSV50403571; called by muse, mutect2, varscan2
- INHBA | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54219300; called by muse, mutect2, varscan2
- JCAD | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs190112050; called by muse, mutect2, varscan2
- KARS1 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56690623; called by muse, mutect2, varscan2
- KCNT2 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs1266098926, COSV54063044; called by muse, mutect2, varscan2
- KIAA1210 | c.3581A>G p.Q1194R | Missense Mutation (SNP) | VAF 106/114 reads (93%) | SIFT tolerated (0.2); PolyPhen benign (0.191); catalogued as COSV68175322; called by muse, mutect2, varscan2
- LRRC43 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs774938224, COSV60287884; called by muse, mutect2, varscan2
- MAP3K2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61292935; called by muse, mutect2, varscan2
- MAP9 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60903274; called by muse, mutect2, varscan2
- MAPKAPK5 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1372322864, COSV72431604; called by muse, mutect2, varscan2
- MBD6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 60/97 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV60764718, COSV60766289; called by muse, mutect2, varscan2
- MCFD2 | c.242A>T p.D81V | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1411125, COSV60177698; called by muse, mutect2, varscan2
- MCOLN1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 77/508 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1281300485, COSV51173860; called by muse, mutect2, varscan2
- MOV10L1 | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs778578765, COSV53167072; called by muse, mutect2, varscan2
- MUC16 | c.6233C>A p.S2078Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV67442870, COSV67486793; called by muse, mutect2, varscan2
- MUC16 | c.2111G>T p.R704I | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV67442876, COSV67478204; called by muse, mutect2, varscan2
- NEPRO | c.1667A>G p.D556G | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99868263; called by muse, mutect2
- NFXL1 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs756955581, COSV61197941; called by muse, mutect2, varscan2
- NLRP8 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV52583022; called by muse, mutect2, varscan2
- NLRP9 | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs199518376, COSV60459247; called by muse, mutect2, varscan2
- NSMAF | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50683639; called by muse, mutect2, varscan2
- OBSCN | c.6836C>T p.S2279L | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747078519, COSV52809897; called by muse, mutect2, varscan2
- OPCML | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs749718972, COSV59402476; called by muse, mutect2, varscan2
- OR4N2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 222/862 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV60049827; called by muse, mutect2, varscan2
- PCDH7 | c.2165G>T p.R722I | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100687759; called by muse, mutect2, varscan2
- PCDHAC2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.888); catalogued as rs369053625; called by muse, mutect2, varscan2
- PPARGC1A | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 319/986 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV53524134, COSV53526922; called by muse, mutect2, varscan2
- PTPRM | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1478345370, COSV59843082; called by muse, mutect2, varscan2
- SELPLG | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201172154; called by muse, mutect2, varscan2
- SHKBP1 | c.1882T>A p.S628T | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.132); catalogued as COSV52537432; called by muse, mutect2, varscan2
- SLC26A11 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs139242541; called by muse, mutect2
- SLC26A5 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 51/200 reads (26%) | catalogued as rs763702424, COSV59697821; called by muse, mutect2, varscan2
- SLX4 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV53560613; called by muse, mutect2, varscan2
- SOHLH2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 109/187 reads (58%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.028); catalogued as rs12873478; called by muse, mutect2, varscan2
- TAF1L | c.1994dup p.A666Gfs*38 | Frame Shift Ins (INS) | VAF 140/404 reads (35%) | catalogued as rs760628590; called by mutect2, varscan2
- TANC2 | c.5008G>A p.D1670N | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.971); catalogued as COSV67329679; called by muse, mutect2, varscan2
- TBC1D9 | c.2984C>A p.A995E | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs780361680, COSV71306764; called by muse, mutect2, varscan2
- TNFSF9 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750244943, COSV55537741; called by muse, mutect2, varscan2
- TTLL8 | c.1332C>T p.S444= | Splice Region (SNP) | VAF 27/66 reads (41%) | catalogued as rs1403980181, COSV99838127; called by muse, mutect2, varscan2
- UBE2R2 | c.444C>A p.F148L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV54287491; called by muse, mutect2, varscan2
- UGT1A1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59381161, COSV59395422; called by muse, mutect2, varscan2
- ZMIZ2 | c.2647G>T p.A883S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54805872; called by muse, mutect2, varscan2
- ZNF493 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.282); catalogued as COSV62749083; called by muse, mutect2, varscan2
- ZNF514 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 121/234 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs148267191; called by muse, mutect2, varscan2
- FOXD4L4 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); called by mutect2, varscan2
- LINC02843 | n.220_220+5del | Splice Site (DEL) | VAF 58/188 reads (31%) | called by mutect2, pindel, varscan2
- ABCC12 | c.2424C>T p.S808= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs556682934, COSV60911372; called by muse, mutect2, varscan2
- AGBL5 | c.1710G>A p.A570= | Silent (SNP) | VAF 54/201 reads (27%) | catalogued as rs372114447; called by muse, mutect2, varscan2
- ARID4B | c.1987C>A p.R663= | Silent (SNP) | VAF 148/432 reads (34%) | catalogued as COSV51597949, COSV51602687; called by muse, mutect2, varscan2
- ATL3 | c.1359T>G p.A453= | Silent (SNP) | VAF 67/153 reads (44%) | catalogued as COSV60295156; called by muse, mutect2, varscan2
- GRID1 | c.507C>T p.Y169= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs368572646; called by muse, mutect2, varscan2
- HCN1 | c.1908C>T p.I636= | Silent (SNP) | VAF 108/250 reads (43%) | catalogued as COSV57492543, COSV57537064; called by muse, mutect2, varscan2
- HSD17B14 | c.426G>A p.L142= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV54412330; called by muse, mutect2, varscan2
- LIG1 | c.2199C>T p.Y733= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs142775724; called by muse, mutect2, varscan2
- NRG2 | c.1653A>G p.A551= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV56828857; called by muse, mutect2, varscan2
- NUDT18 | c.180C>A p.I60= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV57156888; called by muse, mutect2, varscan2
- PCDHA7 | c.1338C>T p.A446= | Silent (SNP) | VAF 111/315 reads (35%) | catalogued as rs782240945, COSV65341622; called by muse, mutect2, varscan2
- PCDHB3 | c.1554G>A p.S518= | Silent (SNP) | VAF 106/259 reads (41%) | catalogued as COSV50564013; called by muse, varscan2
- PEG3 | c.2430C>T p.F810= | Silent (SNP) | VAF 74/321 reads (23%) | catalogued as rs1240769382, COSV55626829; called by muse, mutect2, varscan2
- PRAMEF20 | c.1272C>T p.I424= | Silent (SNP) | VAF 14/466 reads (3%) | catalogued as rs1384564211; called by muse, mutect2
- RYR1 | c.11205G>A p.L3735= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV62088093; called by muse, mutect2, varscan2
- ST13 | c.21C>T p.N7= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV53420682; called by muse, mutect2, varscan2
- ST8SIA2 | c.741C>T p.G247= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs142357478, COSV51569935; called by muse, mutect2, varscan2
- SYCP2L | c.2379T>C p.A793= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as COSV51649674; called by muse, mutect2, varscan2
- TRIB1 | c.579C>T p.V193= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs774222003, COSV61334152; called by muse, mutect2, varscan2
- TRIB2 | c.348C>A p.I116= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV50223857; called by muse, mutect2, varscan2
- TRIM45 | c.1251G>A p.T417= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV56712421; called by muse, mutect2, varscan2
- UBE3B | c.3021C>T p.T1007= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs1053261554, COSV61072728; called by muse, mutect2, varscan2
- VLDLR | c.2577G>A p.T859= | Silent (SNP) | VAF 65/181 reads (36%) | catalogued as rs769064973, COSV66077202; ClinVar: likely benign; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.757G>A | RNA (SNP) | VAF 53/90 reads (59%) | catalogued as rs782137869; called by muse, mutect2, varscan2
- OBSCN | c.11659+3544G>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99474950; called by muse, mutect2
- OGFOD3 | c.824-1895C>T | Intron (SNP) | VAF 79/155 reads (51%) | catalogued as rs577942429, COSV57338995, COSV57342913; called by muse, mutect2, varscan2
- TRIM51 | c.*1C>T | 3'UTR (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99792296; called by muse, varscan2
